Somatic mutation profile of tumor specimen MBCProject_0375_T1_A_WES (aliquot MBCProject_0375_T1_A_WES_1) from CMI case MBCProject_0375, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Tissue or organ of origin: Breast, NOS.
Specimen MBCProject_0375_T1_A_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 72d8b96d-9618-4681-8d29-a9c60bae4eed.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_0375_SALIVA (Saliva), aliquot MBCProject_0375_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dff274ea-0697-4395-888e-b9300184a8c3

The open-access MAF lists 21 somatic variants for this specimen: 11 protein-altering or splice-affecting, 7 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 7, RNA 2, Splice Site 1, Intron 1, Splice Region 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARHGEF25 | c.731G>A p.R244H | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as rs1350372396; called by muse, mutect2, varscan2
- INPP5F | c.613-4C>G | Splice Region (SNP) | VAF 12/110 reads (11%) | catalogued as rs1446004413, COSV100740128; called by muse, varscan2
- SNRNP200 | c.1307G>A p.R436H | Missense Mutation (SNP) | VAF 34/257 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.304); catalogued as rs1322412557, COSV60487895; called by muse, mutect2, varscan2
- TUBE1 | c.1286A>G p.Y429C | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs868930152; called by muse, mutect2
- AKAP7 | c.959A>G p.Q320R (on ENST00000431975 / NM_016377.4; = p.Q53R on NM_004842.4) | Missense Mutation (SNP) | VAF 13/116 reads (11%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- BMP2K | c.421C>G p.Q141E | Missense Mutation (SNP) | VAF 96/226 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.246); called by muse, mutect2, varscan2
- ESRRA | c.394C>G p.Q132E | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- KRT1 | c.504G>T p.E168D | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.605); called by muse, mutect2, varscan2
- SLC16A2 | c.1309G>T p.E437* | Nonsense Mutation (SNP) | VAF 23/165 reads (14%) | called by muse, mutect2, varscan2
- SPEF2 | c.978_978+6del p.X326_splice | Splice Site (DEL) | VAF 9/27 reads (33%) | called by mutect2, pindel, varscan2
- YY1 | c.281C>T p.P94L | Missense Mutation (SNP) | VAF 45/389 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ALDH1L2 | c.648A>G p.P216= | Silent (SNP) | VAF 22/235 reads (9%) | called by muse, mutect2
- INPP5A | c.351C>T p.I117= | Silent (SNP) | VAF 28/252 reads (11%) | catalogued as rs776545394; called by muse, varscan2
- MFAP3L | c.732G>A p.P244= | Silent (SNP) | VAF 29/129 reads (22%) | catalogued as rs138351719; called by muse, mutect2, varscan2
- MUC5AC | c.15378A>T p.T5126= | Silent (SNP) | VAF 8/82 reads (10%) | called by muse, varscan2
- NLRP8 | c.1872A>G p.Q624= | Silent (SNP) | VAF 13/194 reads (7%) | called by muse, mutect2
- TBPL2 | c.231G>A p.P77= | Silent (SNP) | VAF 51/240 reads (21%) | catalogued as rs568763103; called by muse, mutect2, varscan2
- ZNF784 | c.552G>A p.A184= | Silent (SNP) | VAF 6/78 reads (8%) | called by muse, mutect2
- INPP5F | c.612+32C>T | Intron (SNP) | VAF 13/75 reads (17%) | catalogued as rs757628686; called by muse, varscan2
- NXF5 | n.629C>T | RNA (SNP) | VAF 20/145 reads (14%) | catalogued as rs772831793; called by muse, mutect2, varscan2
- TEKT4P2 | n.1445G>T | RNA (SNP) | VAF 15/415 reads (4%) | called by muse, mutect2
